Somatic mutation profile of tumor specimen TCGA-AG-A015-01A (aliquot TCGA-AG-A015-01A-01D-A183-10) from TCGA case TCGA-AG-A015, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 64.3 years (23,496 days).
Specimen TCGA-AG-A015-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ef51f1b0-0261-4563-a6be-3bd8cf4ae342.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-A015-10A (Blood Derived Normal), aliquot TCGA-AG-A015-10A-01W-A00K-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/64c01485-ba8d-41b4-b774-08e4dca58bee

The open-access MAF lists 13 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Frame Shift Del 3, Nonsense Mutation 2, Silent 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HIVEP2 | c.4294G>A p.V1432M | Missense Mutation (SNP) | VAF 30/162 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as rs920504937, COSV50077305; called by muse, mutect2, varscan2
- KIAA0232 | c.890C>G p.S297* | Nonsense Mutation (SNP) | VAF 41/96 reads (43%) | catalogued as COSV56929710; called by muse, mutect2, varscan2
- MOGS | c.838C>T p.R280C | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as rs372551243; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PARD3B | c.1579A>T p.I527F | Missense Mutation (SNP) | VAF 130/324 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV104414953; called by muse, mutect2, varscan2
- PCDHA9 | c.2141C>T p.T714M | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.29); catalogued as rs782210334, COSV65333304; called by muse, mutect2, varscan2
- RUFY2 | c.457del p.M153Wfs*8 | Frame Shift Del (DEL) | VAF 25/232 reads (11%) | catalogued as rs759904440; called by mutect2, varscan2
- USF3 | c.439del p.I147Lfs*22 | Frame Shift Del (DEL) | VAF 20/175 reads (11%) | catalogued as rs747493460; called by mutect2, varscan2
- ZNF512B | c.253C>T p.R85* | Nonsense Mutation (SNP) | VAF 232/435 reads (53%) | catalogued as COSV53871020; called by muse, varscan2
- CAPZB | c.261del p.M88Cfs*6 | Frame Shift Del (DEL) | VAF 94/278 reads (34%) | called by mutect2, pindel, varscan2
- MYH2 | c.2811G>T p.E937D | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.007); called by muse, varscan2
- CALHM2 | c.75C>T p.N25= | Silent (SNP) | VAF 24/57 reads (42%) | catalogued as rs151104032; called by muse, mutect2, varscan2
- CPAMD8 | c.1614G>C p.R538= (on ENST00000651564; = p.R491= on NM_015692.5) | Silent (SNP) | VAF 60/167 reads (36%) | catalogued as COSV52240612; called by muse, mutect2, varscan2
- TMPRSS2 | c.*1T>A | 3'UTR (SNP) | VAF 94/228 reads (41%) | called by muse, varscan2
